Somatic mutation profile of tumor specimen TARGET-10-PAPERW-09A (aliquot TARGET-10-PAPERW-09A-01D) from TARGET case TARGET-10-PAPERW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,002 days).
Specimen TARGET-10-PAPERW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77c2776f-52ed-4c6e-afc8-24a56ad01c91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPERW-14A (Bone Marrow Normal), aliquot TARGET-10-PAPERW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dca058b9-a91a-44e7-98c5-c0158b637ddb

The open-access MAF lists 21 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 4, Silent 4, 5'UTR 1, 5'Flank 1, RNA 1, Splice Region 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN2 | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs772909106, COSV63973777; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397507509, CD041931, CM021126, CX060726, COSV100692385, COSV61005028, COSV61006397; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- FBXW2 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs753802368; called by muse, mutect2, varscan2
- LRCH2 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 27/57 reads (47%) | catalogued as COSV57756689; called by muse, mutect2, varscan2
- MED12 | c.397-2A>C p.X133_splice | Splice Site (SNP) | VAF 13/105 reads (12%) | catalogued as COSV100378324; called by muse, mutect2, varscan2
- TENM3 | c.6448C>T p.R2150W | Missense Mutation (SNP) | VAF 69/247 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs745926916, COSV69300011; called by muse, mutect2, varscan2
- FAM47C | c.1525C>T p.H509Y | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- IRS4 | c.3361G>A p.A1121T | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH2 | c.4371G>A p.K1457= | Splice Region (SNP) | VAF 58/191 reads (30%) | called by muse, mutect2, varscan2
- RNF19B | c.1658A>T p.D553V | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CCDC120 | c.951C>A p.L317= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- G6PD | c.1272C>T p.Y424= | Silent (SNP) | VAF 63/249 reads (25%) | catalogued as rs186843026; called by muse, mutect2, varscan2
- LCORL | c.495A>T p.I165= | Silent (SNP) | VAF 33/116 reads (28%) | called by muse, mutect2, varscan2
- TENM2 | c.6882C>T p.S2294= (on ENST00000518659 / NM_001122679.2; = p.S2055= on NM_001080428.3) | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs758474212, COSV69128760; called by muse, mutect2, varscan2
- CNTRL | c.-387C>G | 5'UTR (SNP) | VAF 16/32 reads (50%) | called by mutect2, varscan2
- DDX17 | c.1447+1542T>C | Intron (SNP) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- DDX17 | c.1447+1540_1447+1541insGGG | Intron (INS) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- DNM3 | c.1689+1605T>A | Intron (SNP) | VAF 7/167 reads (4%) | called by muse, mutect2
- HDAC8 | c.738-10706G>C | Intron (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- NEBL | chr10:20899420 C>T | 5'Flank (SNP) | VAF 12/49 reads (24%) | catalogued as rs772289418; called by muse, mutect2, varscan2
- OR52B1P | n.67G>A | RNA (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
